TCGA case TCGA-3A-A9IH — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10f0d40b-c4c4-441b-9cfb-bef5e44aa91e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.1; Tissue or organ of origin: Body of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 66.2 years (24,174 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,021 days (2.8 years); Sites of involvement: Pancreas Body.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 8; Tumor largest dimension diameter: 2 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 71 days; Days to treatment end: 237 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Days to treatment start: 379 days (1.0 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 379 days (1.0 years); Days to treatment end: 538 days (1.5 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Days to treatment start: 763 days (2.1 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 68.3 years (24,937 days); Days to diagnosis: 763 days (2.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 763 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 763 days (2.1 years); Evidence of progression type: Positive Biomarker(s).
- Days to follow up: 874 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 1,021 days (2.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Chronic Pancreatitis; Risk factors: Chronic Pancreatitis.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2002.
- Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Alcohol drinks per day: 1; Alcohol days per week: 7.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3A-A9IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-3A-A9IH-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-3A-A9IH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3A-A9IH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tissue Biopsy; Surgical procedure: Other Method (please specify); Lymph nodes examined: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Alcohol exposure intensity: Daily Drinker; Alcohol consumption frequency: 7; Diabetes diagnosis indicator: No; History chronic pancreatitis: Yes; Surgical procedure other: Subtotal pancreatectomy and splenectomy and cholecystectomy.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 3: Pharmaceutical therapy drug name: 5-FU.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,021 days; disease-specific survival: no event (censored), 1,021 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 763 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3A-A9IH-01A-12D-A396-01): tumor purity 0.88, ploidy 1.84, whole-genome doublings 0.
